Somatic mutation profile of cancer-model specimen HCM-CSHL-0323-C20-85A (3D Organoid; aliquot HCM-CSHL-0323-C20-85A-01D-A78T-36), derived from the primary tumor of HCMI case HCM-CSHL-0323-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 54.2 years (19,788 days).
Specimen HCM-CSHL-0323-C20-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 699a0c77-fad2-44b7-a0ce-6f2ac06f367a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0323-C20-10A (Blood Derived Normal), aliquot HCM-CSHL-0323-C20-10A-01D-A78T-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/decee06c-f0aa-4e4b-8d3f-3dce52a5f23f

The open-access MAF lists 111 somatic variants for this specimen: 73 protein-altering or splice-affecting, 27 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 27, Nonsense Mutation 4, 5'UTR 4, Intron 3, 3'Flank 2, Frame Shift Ins 1, In Frame Del 1, 3'UTR 1, RNA 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP6V1B1 | c.340C>T p.R114* | Nonsense Mutation (SNP) | VAF 97/368 reads (26%) | catalogued as rs782138777, CM088308; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.467G>C p.R156P | Missense Mutation (SNP) | VAF 260/260 reads (100%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.876); catalogued as rs371524413, CM984589, COSV52698013, COSV52700732, COSV52710835, COSV52891661; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AFF1 | c.1171G>T p.D391Y | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100320468; called by muse, mutect2, varscan2
- AGBL1 | c.2294C>T p.T765M | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767364604, COSV101224391, COSV66858368; called by muse, mutect2, varscan2
- AL645922.1 | c.1081G>A p.D361N | Missense Mutation (SNP) | VAF 304/658 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs751852076, COSV54960479; called by muse, mutect2, varscan2
- AMER1 | c.1901G>A p.R634H | Missense Mutation (SNP) | VAF 449/449 reads (100%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs778813513; called by muse, mutect2, varscan2
- ARHGAP21 | c.5810C>T p.A1937V | Missense Mutation (SNP) | VAF 55/121 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs771670801; called by muse, mutect2, varscan2
- ATG2B | c.4601C>G p.T1534R | Missense Mutation (SNP) | VAF 102/239 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.223); catalogued as COSV104379645; called by muse, mutect2, varscan2
- CCDC80 | c.1411C>T p.R471W | Missense Mutation (SNP) | VAF 228/342 reads (67%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs769656953, COSV99244981; called by muse, mutect2, varscan2
- CCER1 | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 54/98 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62647334; called by muse, mutect2, varscan2
- CNTNAP2 | c.611A>T p.K204M | Missense Mutation (SNP) | VAF 107/475 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.449); catalogued as COSV62242531; called by muse, mutect2, varscan2
- DCAF4L2 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 81/259 reads (31%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as rs1279696544, COSV60476552; called by muse, mutect2, varscan2
- DMD | c.5795A>T p.Q1932L | Missense Mutation (SNP) | VAF 59/97 reads (61%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.839); catalogued as COSV63790408; called by muse, mutect2, varscan2
- FAF2 | c.1217A>G p.N406S | Missense Mutation (SNP) | VAF 223/223 reads (100%) | SIFT tolerated (0.05); PolyPhen benign (0.147); catalogued as rs1028677538; called by muse, mutect2, varscan2
- GALNTL6 | c.47C>T p.T16M | Missense Mutation (SNP) | VAF 107/257 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV72552951; called by muse, mutect2, varscan2
- H1-4 | c.277_297del p.L93_T99del | In Frame Del (DEL) | VAF 114/369 reads (31%) | catalogued as rs775218240; called by mutect2, varscan2
- HECW1 | c.4463C>T p.A1488V | Missense Mutation (SNP) | VAF 111/533 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.079); catalogued as rs192568048; called by muse, mutect2, varscan2
- HEY2 | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 69/126 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV64240160; called by muse, mutect2, varscan2
- HM13 | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 91/415 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV100159626; called by muse, mutect2, varscan2
- IGSF9B | c.2875C>T p.R959W | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs775176299; called by muse, mutect2, varscan2
- MYT1L | c.2255C>T p.P752L | Missense Mutation (SNP) | VAF 134/271 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV67730062; called by muse, mutect2, varscan2
- NPIPB11 | c.1391C>T p.P464L | Missense Mutation (SNP) | VAF 525/1278 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.913); catalogued as rs775513952; called by muse, varscan2
- NPIPB11 | c.1139C>T p.P380L | Missense Mutation (SNP) | VAF 43/324 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs746066168; called by muse, varscan2
- NSMF | c.764C>T p.A255V (on ENST00000371475 / NM_001130969.3; = p.A253V on NM_015537.4) | Missense Mutation (SNP) | VAF 236/758 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs1281484579, COSV52996791; called by muse, mutect2, varscan2
- PAPPA2 | c.1739G>A p.R580Q | Missense Mutation (SNP) | VAF 93/212 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); catalogued as rs777147973, COSV62783931; called by muse, mutect2, varscan2
- PCDHA1 | c.1339G>A p.D447N | Missense Mutation (SNP) | VAF 256/538 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV65372473; called by muse, mutect2, varscan2
- PMCH | c.181C>A p.P61T | Missense Mutation (SNP) | VAF 98/205 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as COSV100268343; called by muse, varscan2
- PPP1R9A | c.2513G>A p.R838K | Missense Mutation (SNP) | VAF 39/191 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.036); catalogued as COSV56883912; called by muse, mutect2, varscan2
- PTPRA | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 123/270 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.678); catalogued as rs1012156940, COSV53786521; called by muse, mutect2, varscan2
- RTL4 | c.251C>A p.A84D | Missense Mutation (SNP) | VAF 76/76 reads (100%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100465994; called by muse, mutect2, varscan2
- SLC6A5 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 115/249 reads (46%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.007); catalogued as rs750833001, COSV54227304; called by muse, mutect2, varscan2
- SOD3 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 263/549 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.131); catalogued as rs1214005453; called by muse, mutect2, varscan2
- SSNA1 | c.53G>A p.C18Y | Missense Mutation (SNP) | VAF 98/308 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.274); catalogued as rs1388709781; called by muse, mutect2, varscan2
- TAL1 | c.857C>T p.S286F | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750834196, COSV53747247; called by muse, mutect2, varscan2
- THOC7 | c.167C>T p.T56M | Missense Mutation (SNP) | VAF 144/270 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.094); catalogued as rs745955974; called by muse, mutect2, varscan2
- WHRN | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 169/480 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as rs1388198744; called by muse, mutect2, varscan2
- ZFP36L2 | c.418C>T p.Q140* | Nonsense Mutation (SNP) | VAF 1142/1142 reads (100%) | catalogued as COSV56698061; called by muse, mutect2, varscan2
- ZNF215 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 89/185 reads (48%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs780015579, COSV53491912; called by muse, mutect2, varscan2
- ZNF454 | c.1202G>A p.R401Q | Missense Mutation (SNP) | VAF 82/158 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.11); catalogued as rs780417342, COSV60766966; called by muse, mutect2, varscan2
- ZNF462 | c.3619G>T p.G1207W | Missense Mutation (SNP) | VAF 86/299 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99473232; called by muse, mutect2, varscan2
- ZNF536 | c.669C>A p.D223E | Missense Mutation (SNP) | VAF 101/217 reads (47%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.654); catalogued as rs1473327018; called by muse, mutect2, varscan2
- AADAC | c.1196T>G p.L399R | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- AGRN | c.1157C>T p.S386F | Missense Mutation (SNP) | VAF 136/291 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); called by muse, varscan2
- ANK2 | c.8874A>T p.E2958D | Missense Mutation (SNP) | VAF 155/308 reads (50%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- BAALC | c.397C>G p.L133V (on ENST00000297574 / NM_001364874.1; = p.L98V on NM_024812.3) | Missense Mutation (SNP) | VAF 68/222 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- CACNA1C | c.1352A>G p.N451S | Missense Mutation (SNP) | VAF 82/329 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- CASR | c.2661G>T p.Q887H (on ENST00000490131; = p.Q964H on NM_000388.4) | Missense Mutation (SNP) | VAF 531/807 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- CEP44 | c.553G>T p.D185Y | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.043); called by muse, mutect2
- CHFR | c.28T>C p.S10P | Missense Mutation (SNP) | VAF 63/154 reads (41%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL5A2 | c.854G>A p.G285E | Missense Mutation (SNP) | VAF 119/577 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DCAF12L2 | c.150G>T p.R50S | Missense Mutation (SNP) | VAF 176/369 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAJC19 | c.106G>C p.V36L | Missense Mutation (SNP) | VAF 187/601 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ERI1 | c.966G>T p.M322I | Missense Mutation (SNP) | VAF 130/130 reads (100%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM155A | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0); called by muse, mutect2, varscan2
- FLACC1 | c.694A>T p.M232L | Missense Mutation (SNP) | VAF 45/215 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HMGA2 | c.80G>T p.R27I | Missense Mutation (SNP) | VAF 100/412 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- ITGAX | c.1715T>A p.I572N | Missense Mutation (SNP) | VAF 123/368 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- KRTAP13-1 | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 166/302 reads (55%) | SIFT tolerated (0.52); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LRGUK | c.1099G>T p.E367* | Nonsense Mutation (SNP) | VAF 16/70 reads (23%) | called by muse, mutect2, varscan2
- MGAT5 | c.1923G>T p.K641N | Missense Mutation (SNP) | VAF 133/504 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- MOBP | c.266C>T p.A89V (on ENST00000420739; = p.A113V on NM_001278322.2) | Missense Mutation (SNP) | VAF 148/462 reads (32%) | PolyPhen benign (0.007); called by muse, varscan2
- MSI1 | c.63G>T p.K21N | Missense Mutation (SNP) | VAF 88/187 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- PAX3 | c.899C>T p.P300L | Missense Mutation (SNP) | VAF 123/434 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- POLB | c.287C>A p.S96Y | Missense Mutation (SNP) | VAF 84/622 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.178); called by muse, varscan2
- PRAMEF6 | c.354dup p.A119Sfs*44 | Frame Shift Ins (INS) | VAF 23/63 reads (37%) | called by mutect2, pindel, varscan2
- SLC4A2 | c.247C>T p.H83Y | Missense Mutation (SNP) | VAF 59/274 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- TBC1D32 | c.208A>T p.M70L | Missense Mutation (SNP) | VAF 61/150 reads (41%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TG | c.3696G>T p.E1232D | Missense Mutation (SNP) | VAF 163/511 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMC3 | c.1323C>G p.F441L | Missense Mutation (SNP) | VAF 128/248 reads (52%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, varscan2
- USP19 | c.52G>T p.E18* | Nonsense Mutation (SNP) | VAF 61/222 reads (27%) | called by muse, mutect2, varscan2
- XPO4 | c.2131G>C p.V711L | Missense Mutation (SNP) | VAF 58/190 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- ZNF638 | c.2294A>G p.E765G | Missense Mutation (SNP) | VAF 52/52 reads (100%) | SIFT tolerated (0.14); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ZSWIM2 | c.1741G>C p.V581L | Missense Mutation (SNP) | VAF 54/211 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADAMTS16 | c.2094C>G p.V698= | Silent (SNP) | VAF 56/115 reads (49%) | catalogued as rs779376714, COSV56983966; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2658C>T p.F886= | Silent (SNP) | VAF 86/275 reads (31%) | called by muse, mutect2, varscan2
- AMPD2 | c.1905G>A p.G635= | Silent (SNP) | VAF 48/73 reads (66%) | called by muse, mutect2, varscan2
- CAND2 | c.1311G>T p.V437= (on ENST00000456430 / NM_001162499.2; = p.V344= on NM_012298.3) | Silent (SNP) | VAF 63/196 reads (32%) | called by muse, mutect2, varscan2
- DCAF1 | c.3322C>T p.L1108= | Silent (SNP) | VAF 80/311 reads (26%) | called by muse, mutect2, varscan2
- DSP | c.7149C>T p.S2383= | Silent (SNP) | VAF 45/99 reads (45%) | called by muse, mutect2, varscan2
- EPHB6 | c.171C>T p.D57= | Silent (SNP) | VAF 156/675 reads (23%) | catalogued as rs780410425; called by muse, mutect2, varscan2
- EPS15L1 | c.606C>T p.S202= | Silent (SNP) | VAF 86/156 reads (55%) | catalogued as rs767315898, COSV50169599; called by muse, mutect2, varscan2
- FKRP | c.786C>T p.R262= | Silent (SNP) | VAF 58/102 reads (57%) | catalogued as rs1430767903; called by muse, mutect2, varscan2
- HEG1 | c.2172G>A p.T724= | Silent (SNP) | VAF 163/568 reads (29%) | called by muse, mutect2, varscan2
- HEMGN | c.1224C>T p.L408= | Silent (SNP) | VAF 201/668 reads (30%) | called by muse, mutect2, varscan2
- HOXA1 | c.900G>A p.P300= | Silent (SNP) | VAF 418/547 reads (76%) | catalogued as rs752269739, COSV58030183; called by muse, mutect2, varscan2
- HSP90AA1 | c.180G>C p.R60= | Silent (SNP) | VAF 106/238 reads (45%) | called by muse, mutect2, varscan2
- JPH3 | c.969C>T p.Y323= | Silent (SNP) | VAF 126/250 reads (50%) | catalogued as rs376157795; called by muse, mutect2, varscan2
- LRRC7 | c.261G>A p.E87= (on ENST00000651989 / NM_001370785.2; = p.E54= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 122/257 reads (47%) | catalogued as rs770324406, COSV50547803; called by muse, mutect2, varscan2
- METTL6 | c.576G>A p.L192= | Silent (SNP) | VAF 61/225 reads (27%) | called by muse, mutect2, varscan2
- NCOR1 | c.5295G>A p.E1765= | Silent (SNP) | VAF 59/110 reads (54%) | called by muse, mutect2, varscan2
- NYX | c.468C>T p.A156= | Silent (SNP) | VAF 107/231 reads (46%) | called by muse, mutect2, varscan2
- OR8H2 | c.507C>T p.Y169= | Silent (SNP) | VAF 82/168 reads (49%) | catalogued as rs576066178, COSV57944167, COSV57947973; called by muse, mutect2, varscan2
- PLAT | c.732G>A p.L244= | Silent (SNP) | VAF 56/401 reads (14%) | called by muse, mutect2, varscan2
- PLEKHA4 | c.1593C>T p.S531= | Silent (SNP) | VAF 26/63 reads (41%) | catalogued as rs767414198; called by muse, mutect2, varscan2
- PRPF40A | c.1770C>T p.A590= | Silent (SNP) | VAF 63/404 reads (16%) | called by muse, mutect2, varscan2
- RYR3 | c.2253C>A p.P751= | Silent (SNP) | VAF 111/254 reads (44%) | called by muse, mutect2, varscan2
- SWSAP1 | c.156C>T p.T52= (on ENST00000312423; = p.T73= on NM_175871.4) | Silent (SNP) | VAF 152/388 reads (39%) | called by muse, varscan2
- TRPS1 | c.1752G>A p.P584= (on ENST00000220888 / NM_001330599.2; = p.P597= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 97/322 reads (30%) | catalogued as rs1460762540, COSV99629754; called by muse, mutect2, varscan2
- ZNF133 | c.1425C>T p.F475= (on ENST00000316358 / NM_001352454.2; = p.F474= on NM_003434.7 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 36/152 reads (24%) | called by muse, mutect2, varscan2
- ZNF835 | c.936C>T p.G312= | Silent (SNP) | VAF 154/355 reads (43%) | catalogued as rs776603650, COSV73379206, COSV73379497; called by muse, mutect2, varscan2
- ABCA8 | c.3918+43A>G | Intron (SNP) | VAF 67/123 reads (54%) | called by muse, mutect2, varscan2
- ASL | c.*34G>A | 3'UTR (SNP) | VAF 488/676 reads (72%) | catalogued as rs548464700, COSV59189353; called by muse, mutect2, varscan2
- CXCL3 | c.308+37C>T | Intron (SNP) | VAF 77/175 reads (44%) | called by muse, mutect2, varscan2
- GMFB | c.-6A>G | 5'UTR (SNP) | VAF 66/133 reads (50%) | called by muse, mutect2, varscan2
- GPR180 | c.-5C>T | 5'UTR (SNP) | VAF 62/183 reads (34%) | called by muse, mutect2, varscan2
- HSD17B12 | c.-16G>A | 5'UTR (SNP) | VAF 94/208 reads (45%) | catalogued as rs1467937755; called by muse, mutect2, varscan2
- LINC01164 | n.1029G>A | RNA (SNP) | VAF 85/144 reads (59%) | catalogued as rs192498630; called by muse, mutect2, varscan2
- REXO1L1P | chr8:85655105 C>T | 3'Flank (SNP) | VAF 298/2815 reads (11%) | catalogued as rs757619904; called by muse, mutect2, varscan2
- RN7SL545P | chr15:22427727 C>T | 3'Flank (SNP) | VAF 70/246 reads (28%) | catalogued as rs770359092; called by mutect2, varscan2
- SYCP2 | c.-4C>A | 5'UTR (SNP) | VAF 24/139 reads (17%) | called by muse, mutect2, varscan2
- TAFA5 | c.112+54995C>T | Intron (SNP) | VAF 78/163 reads (48%) | catalogued as rs923041679; called by muse, mutect2
